Gene-level copy-number profile of tumor specimen TCGA-IR-A3LI-01A from TCGA case TCGA-IR-A3LI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 48.6 years (17,741 days).
Specimen TCGA-IR-A3LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.157bebd4-083b-424d-aa5a-a08e13369b9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IR-A3LI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b55ae35d-3535-4dd7-b4ac-2750c88644f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,790; copy number 2: 53,847; copy number 3: 3,054; copy number 6: 1,129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IR-A3LI-01A-11D-A20T-01): tumor purity 0.93, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,129 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,038,391–198,222,513, 1,129 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
